Somatic mutation profile of tumor specimen TCGA-BC-A217-01A (aliquot TCGA-BC-A217-01A-11D-A152-10) from TCGA case TCGA-BC-A217, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 75.0 years (27,411 days).
Specimen TCGA-BC-A217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8b9b081-5f86-41c4-b91c-c8b3e27d9e72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A217-10A (Blood Derived Normal), aliquot TCGA-BC-A217-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68c4f45c-ca45-4a8a-bfa5-19d040fd03cf

The open-access MAF lists 131 somatic variants for this specimen: 87 protein-altering or splice-affecting, 31 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 31, 3'UTR 9, Frame Shift Del 4, Nonsense Mutation 3, Intron 2, IGR 1, In Frame Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 25/30 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53694512; called by muse, mutect2, varscan2
- ADA2 | c.1443G>T p.K481N (on ENST00000262607; = p.K240N on NM_177405.3) | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs774795047, COSV52832621; called by muse, mutect2, varscan2
- ANKRD12 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1367369048, COSV50836724; called by muse, mutect2, varscan2
- ARHGEF12 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63106323; called by muse, mutect2, varscan2
- CBWD1 | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 240/772 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100070975; called by muse, mutect2, varscan2
- CCDC191 | c.1070T>A p.L357Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV55674635; called by muse, mutect2, varscan2
- CEP295NL | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 129/212 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.633); catalogued as COSV53162109; called by muse, mutect2, varscan2
- CHTF18 | c.2153C>A p.T718N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV50210788; called by muse, mutect2, varscan2
- COL7A1 | c.850A>G p.N284D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as COSV60399604; called by muse, varscan2
- CSMD2 | c.835A>G p.S279G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV53938931; called by muse, mutect2, varscan2
- CUL4B | c.2162T>G p.L721R | Missense Mutation (SNP) | VAF 107/473 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60689755; called by muse, mutect2, varscan2
- DDX60 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 134/228 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV67098155; called by muse, mutect2, varscan2
- DDX60L | c.498G>A p.W166* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as rs1299204704, COSV52718198; called by muse, varscan2
- DHX9 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 90/149 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62361047; called by muse, mutect2, varscan2
- DNAH7 | c.2789T>C p.L930S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56776419; called by muse, mutect2, varscan2
- DNAH9 | c.10226A>T p.Y3409F | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52364647; called by muse, mutect2, varscan2
- DYTN | c.1002C>A p.N334K | Missense Mutation (SNP) | VAF 122/259 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV71752638; called by muse, mutect2, varscan2
- EFCAB8 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777375132; called by muse, mutect2, varscan2
- ERGIC3 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54139775; called by muse, mutect2, varscan2
- FREM2 | c.5708C>T p.P1903L | Missense Mutation (SNP) | VAF 109/166 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54845434; called by muse, mutect2, varscan2
- FSTL4 | c.2478G>C p.E826D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV54779603; called by muse, mutect2, varscan2
- GAREM1 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52507810, COSV52513282; called by muse, mutect2, varscan2
- GEMIN4 | c.2411A>G p.Q804R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56746774; called by muse, mutect2, varscan2
- GRIN3A | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as COSV62456472; called by muse, mutect2, varscan2
- GRM1 | c.2978C>T p.S993F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV51215988; called by muse, mutect2, varscan2
- GSDMC | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV52697516, COSV52700648; called by muse, mutect2, varscan2
- H3C7 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as COSV55100495; called by muse, mutect2, varscan2
- HGD | c.565A>T p.S189C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV52199868; called by muse, mutect2, varscan2
- HGF | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV55959735, COSV99735215; called by muse, mutect2, varscan2
- HIBCH | c.310T>G p.S104A | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62892522; called by muse, mutect2, varscan2
- HOXC4 | c.33C>A p.N11K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV57700063; called by muse, mutect2, varscan2
- IDE | c.2377A>G p.I793V | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV56425744; called by muse, mutect2, varscan2
- IDH3G | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.035); catalogued as COSV54206627; called by muse, mutect2, varscan2
- IRX1 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57361274; called by muse, mutect2, varscan2
- KCNJ3 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54540680; called by muse, mutect2, varscan2
- KLF16 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.534); catalogued as rs986401397, COSV51736922; called by muse, mutect2
- LILRA1 | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV52183117; called by muse, mutect2, varscan2
- MALT1 | c.1475+1G>A p.X492_splice | Splice Site (SNP) | VAF 64/104 reads (62%) | catalogued as rs888212988, COSV61935784; called by muse, mutect2, varscan2
- MCTP2 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV59147313; called by muse, mutect2, varscan2
- NBR1 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV57834306; called by muse, mutect2, varscan2
- NPY5R | c.1166T>A p.V389E | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1341557653, COSV58453097; called by muse, mutect2, varscan2
- OSBPL6 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV51925012; called by muse, mutect2, varscan2
- PCDH7 | c.1866C>A p.S622R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62341418; called by muse, mutect2, varscan2
- PCDH7 | c.2361T>A p.N787K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62341426; called by muse, mutect2, varscan2
- PCDHA6 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV65346186; called by muse, mutect2, varscan2
- PCDHAC2 | c.1256A>G p.Y419C | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782399233, COSV53861682; called by muse, mutect2, varscan2
- PIGN | c.2056A>G p.I686V | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as rs776384729, COSV62950896; called by muse, mutect2, varscan2
- PLA2G3 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 90/160 reads (56%) | catalogued as COSV53211367; called by muse, mutect2, varscan2
- PLEKHO1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs959973169, COSV50310194, COSV50310905; called by muse, mutect2
- PLXNA4 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs533775501, COSV100322360, COSV58146938; called by muse, mutect2, varscan2
- RANBP2 | c.4079G>A p.S1360N | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as rs1305599461, COSV51705448, COSV99312899; called by muse, mutect2, varscan2
- RECQL | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 81/87 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV59085467; called by muse, mutect2, varscan2
- RELN | c.2141G>A p.S714N | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.914); catalogued as rs1439046809, COSV59022013; called by muse, mutect2, varscan2
- RIMS1 | c.2968C>A p.P990T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); catalogued as COSV53471440; called by muse, mutect2, varscan2
- ROBO2 | c.2426A>C p.Q809P | Missense Mutation (SNP) | VAF 80/90 reads (89%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV59910628; called by muse, mutect2, varscan2
- RP1L1 | c.3876A>T p.L1292F | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV66758121; called by muse, mutect2, varscan2
- S100A10 | c.170A>T p.K57M | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1354270242; called by muse, mutect2
- SAA1 | c.174del p.N59Tfs*17 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as rs772901303; called by mutect2, varscan2
- SENP2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV56196244; called by muse, mutect2, varscan2
- SGO2 | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63414011; called by muse, mutect2, varscan2
- SHC4 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60114850; called by muse, mutect2, varscan2
- SHOX2 | c.431G>A p.R144Q (on ENST00000441443 / NM_006884.3; = p.R168Q on NM_003030.4) | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313229623, COSV67464336; called by muse, mutect2, varscan2
- SLC12A5 | c.3362T>G p.L1121R (on ENST00000454036 / NM_001134771.2; = p.L1098R on NM_020708.5) | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51646064; called by muse, mutect2, varscan2
- SLC44A5 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63770153; called by muse, mutect2, varscan2
- SYNE1 | c.18896G>T p.W6299L (on ENST00000367255 / NM_182961.4; = p.W6228L on NM_033071.3) | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55047965; called by muse, mutect2, varscan2
- SYNE2 | c.8004G>T p.L2668F | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs755099726, COSV59961091; called by muse, mutect2, varscan2
- SYT3 | c.1039C>A p.R347S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770412233, COSV58895956, COSV58897212, COSV58898075; called by muse, mutect2, varscan2
- TBC1D14 | c.1819T>C p.F607L | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV68986540; called by muse, mutect2, varscan2
- TCF7L1 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV56398056, COSV56399431; called by muse, mutect2, varscan2
- TMEM175 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.892); catalogued as COSV53280253; called by muse, mutect2, varscan2
- TOM1 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV65898917; called by muse, mutect2, varscan2
- TREM2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV58295279; called by muse, mutect2
- TRIM54 | c.742G>C p.G248R (on ENST00000380075 / NM_187841.3; = p.G290R on NM_032546.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV51991443; called by muse, mutect2
- VPS13A | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 108/202 reads (53%) | catalogued as COSV62434642; called by muse, mutect2, varscan2
- VWA5B1 | c.1485C>A p.N495K | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV57058899; called by muse, mutect2, varscan2
- WAPL | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as COSV53938124; called by muse, mutect2, varscan2
- WIF1 | c.978C>G p.C326W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54134066; called by muse, mutect2, varscan2
- XIRP2 | c.1812G>T p.L604F (on ENST00000628543; = p.L779F on NM_152381.6) | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54720102; called by muse, mutect2, varscan2
- ZBTB40 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65146060; called by muse, mutect2, varscan2
- ZFHX4 | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.957); catalogued as COSV51478725, COSV51489132; called by muse, mutect2, varscan2
- ZNF229 | c.365G>C p.C122S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52163798; called by muse, mutect2, varscan2
- ZNF521 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 100/180 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533662951, COSV64129824; called by muse, varscan2
- CDH22 | c.638del p.G213Afs*13 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel
- FOXD4L4 | c.134_136dup p.E45dup | In Frame Ins (INS) | VAF 71/420 reads (17%) | called by mutect2, varscan2
- PRAMEF18 | c.41_51del p.G14Afs*13 | Frame Shift Del (DEL) | VAF 69/273 reads (25%) | called by mutect2, pindel, varscan2
- SAA2 | c.174del p.N59Tfs*17 | Frame Shift Del (DEL) | VAF 52/287 reads (18%) | called by mutect2, varscan2
- ACVRL1 | c.429C>T p.V143= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs762047618, COSV66360651; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTSL2 | c.192G>A p.G64= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV63203533; called by muse, mutect2, varscan2
- ADGRL3 | c.4722T>C p.A1574= (on ENST00000506720 / NM_001322402.2; = p.A1463= on NM_015236.6) | Silent (SNP) | VAF 51/77 reads (66%) | catalogued as COSV72231376; called by muse, mutect2, varscan2
- AKR1C1 | c.333T>C p.V111= | Silent (SNP) | VAF 121/279 reads (43%) | catalogued as COSV66499576; called by muse, mutect2, varscan2
- ARMC3 | c.1876C>A p.R626= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV53064924, COSV99958324; called by muse, mutect2, varscan2
- BACE2 | c.1068T>A p.P356= | Silent (SNP) | VAF 90/192 reads (47%) | catalogued as COSV57741701; called by muse, mutect2, varscan2
- BAG6 | c.3135A>T p.S1045= (on ENST00000676571; = p.S998= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV52993361; called by muse, mutect2, varscan2
- C1GALT1C1L | c.120C>T p.H40= | Silent (SNP) | VAF 158/335 reads (47%) | catalogued as rs747149020, COSV56758017; called by muse, mutect2, varscan2
- CPNE5 | c.1446C>A p.P482= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV55198496; called by muse, mutect2, varscan2
- CTNND2 | c.3117G>T p.S1039= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV58909404; called by muse, mutect2, varscan2
- DSC2 | c.2235T>A p.P745= | Silent (SNP) | VAF 64/101 reads (63%) | catalogued as COSV51867269; called by muse, mutect2, varscan2
- DTNA | c.1494A>G p.E498= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV52016717; called by muse, mutect2, varscan2
- FAM207A | c.654G>A p.L218= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52421499; called by muse, mutect2
- FOXK1 | c.2193C>T p.T731= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1176617190; called by muse, mutect2
- HGF | c.1449C>A p.P483= | Silent (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- HSPA1L | c.1842A>G p.Q614= | Silent (SNP) | VAF 107/360 reads (30%) | catalogued as COSV65149752, COSV65150966; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1630T>C p.L544= | Silent (SNP) | VAF 103/199 reads (52%) | catalogued as COSV61170438; called by muse, mutect2, varscan2
- ITGAX | c.972T>C p.D324= | Silent (SNP) | VAF 58/87 reads (67%) | catalogued as COSV51649011; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.72C>T p.C24= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs140704362; called by muse, mutect2, varscan2
- LILRA5 | c.207G>T p.G69= | Silent (SNP) | VAF 105/178 reads (59%) | catalogued as rs1327100030, COSV56643018, COSV56644217; called by muse, mutect2, varscan2
- MYLK | c.3531C>T p.G1177= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs936245754, COSV60616715; called by muse, mutect2
- MYO3A | c.3705T>C p.A1235= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV56341091; called by muse, mutect2, varscan2
- NBEAL2 | c.423C>G p.L141= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV52761287, COSV99435574; called by muse, mutect2, varscan2
- OR10P1 | c.75C>A p.G25= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs765405294, COSV59007839; called by muse, mutect2, varscan2
- PCDHB7 | c.2130G>A p.R710= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as rs782522165, COSV50795851; called by muse, mutect2, varscan2
- PDZRN4 | c.2850G>T p.L950= (on ENST00000402685 / NM_001164595.2; = p.L692= on NM_013377.4) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV54210176; called by muse, mutect2, varscan2
- PLEKHO1 | c.1185C>G p.L395= | Silent (SNP) | VAF 16/367 reads (4%) | catalogued as COSV50310916; called by muse, mutect2
- SLFN12 | c.771C>A p.L257= | Silent (SNP) | VAF 58/157 reads (37%) | catalogued as COSV59226997; called by muse, mutect2, varscan2
- SPATA20 | c.1785G>A p.A595= (on ENST00000356488 / NM_001258372.1; = p.A611= on NM_022827.4) | Silent (SNP) | VAF 69/210 reads (33%) | catalogued as rs746708709, COSV50066405; called by muse, mutect2, varscan2
- TMPPE | c.1314G>C p.L438= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV56566406; called by muse, mutect2, varscan2
- TYRO3 | c.1995G>A p.E665= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV55485380; called by muse, mutect2, varscan2
- AJAP1 | c.*3G>A | 3'UTR (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100981796; called by muse, mutect2, varscan2
- DNAJC6 | c.22+44836G>A | Intron (SNP) | VAF 24/101 reads (24%) | catalogued as COSV54779007; called by muse, mutect2, varscan2
- DST | c.4297-1583G>A | Intron (SNP) | VAF 28/108 reads (26%) | catalogued as rs200851382, COSV55020286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.*27T>A | 3'UTR (SNP) | VAF 168/381 reads (44%) | catalogued as COSV100145390; called by muse, mutect2, varscan2
- FUT9 | c.*7778C>T | 3'UTR (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100133705; called by muse, mutect2, varscan2
- GJB4 | c.*118G>T | 3'UTR (SNP) | VAF 31/100 reads (31%) | catalogued as COSV100258497; called by muse, mutect2, varscan2
- GPR65 | c.*195T>C | 3'UTR (SNP) | VAF 32/100 reads (32%) | catalogued as COSV99966072; called by muse, mutect2, varscan2
- KCNC4 | c.*624G>A | 3'UTR (SNP) | VAF 22/33 reads (67%) | catalogued as rs374236746; called by muse, mutect2, varscan2
- MAGEB10 | c.*116T>C | 3'UTR (SNP) | VAF 36/167 reads (22%) | catalogued as COSV100775281; called by muse, mutect2, varscan2
- RGS9BP | c.*22C>T | 3'UTR (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100042853; called by muse, mutect2, varscan2
- RTL6 | c.-100G>T | 5'UTR (SNP) | VAF 6/8 reads (75%) | catalogued as COSV100373768, COSV100373781; called by muse, mutect2
- TRIM13 | c.*4979T>C | 3'UTR (SNP) | VAF 66/90 reads (73%) | catalogued as COSV53950682; called by muse, mutect2, varscan2
- Unknown | chr1:200342688 C>T | IGR (SNP) | VAF 61/121 reads (50%) | catalogued as rs966477468; called by muse, mutect2, varscan2
